Somatic mutation profile of tumor specimen C3L-08296-03 (aliquot CPT0535490009) from CPTAC case C3L-08296, project CPTAC-3 (Stomach — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Stomach, NOS; AJCC pathologic stage: Stage IIA; Tumor grade: G1; Age at diagnosis: 59.5 years (21,715 days).
Specimen C3L-08296-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Antrum; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c5d491c9-ee09-483d-aafd-b68cdbf134ee.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-08296-31 (Blood Derived Normal), aliquot CPT0535590004; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/612c9561-5474-4f32-85cb-70ffe37b04f8

The open-access MAF lists 156 somatic variants for this specimen: 122 protein-altering or splice-affecting, 29 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 109, Silent 29, Nonsense Mutation 8, Splice Region 3, Intron 3, RNA 1, Frame Shift Ins 1, Splice Site 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- COL3A1 | c.3095G>T p.G1032V | Missense Mutation (SNP) | VAF 36/628 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs587779428, CM000354; ClinVar: pathogenic; called by muse, mutect2
- PRSS1 | c.365G>A p.R122H | Missense Mutation (SNP) | VAF 78/994 reads (8%) | SIFT tolerated (0.4); PolyPhen benign (0.001); catalogued as rs111033565, CM961197, CP015809; ClinVar: pathogenic; called by muse, mutect2
- ABCA13 | c.433A>C p.T145P | Missense Mutation (SNP) | VAF 26/426 reads (6%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.862); catalogued as rs752751680; called by muse, mutect2
- ADAMTS4 | c.1657C>T p.R553W | Missense Mutation (SNP) | VAF 46/1029 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as rs755517863, COSV63489709; called by muse, mutect2
- ADAMTS9 | c.3532A>G p.T1178A | Missense Mutation (SNP) | VAF 34/499 reads (7%) | SIFT tolerated (0.82); PolyPhen benign (0); catalogued as rs759944904; called by muse, mutect2
- APOB | c.11945C>A p.A3982E | Missense Mutation (SNP) | VAF 50/807 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.456); catalogued as COSV51931870; called by muse, mutect2
- ATP2B4 | c.391C>T p.L131= | Splice Region (SNP) | VAF 24/420 reads (6%) | catalogued as rs777154265; called by muse, mutect2
- CACNA1E | c.4178G>A p.R1393H | Missense Mutation (SNP) | VAF 45/731 reads (6%) | SIFT tolerated (0.09); PolyPhen benign (0.273); catalogued as rs760283783, COSV62381281; called by muse, mutect2
- CCDC168 | c.18094C>T p.R6032C | Missense Mutation (SNP) | VAF 91/699 reads (13%) | SIFT tolerated (0.95); PolyPhen benign (0.005); catalogued as rs1454294230; called by muse, mutect2, varscan2
- CCDC77 | c.143G>A p.R48H | Missense Mutation (SNP) | VAF 44/812 reads (5%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as rs200513629; called by muse, mutect2
- CDAN1 | c.2456G>A p.R819Q | Missense Mutation (SNP) | VAF 48/682 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.585); catalogued as rs775821246, COSV62334117; called by muse, mutect2
- COL3A1 | c.1502G>C p.G501A | Missense Mutation (SNP) | VAF 29/475 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM123161, COSV58582580; called by muse, mutect2
- COL6A5 | c.5005C>T p.P1669S | Missense Mutation (SNP) | VAF 26/592 reads (4%) | SIFT tolerated (0.29); PolyPhen benign (0.01); catalogued as rs894168503; called by muse, mutect2
- CTTNBP2 | c.4890C>A p.S1630R | Missense Mutation (SNP) | VAF 58/654 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.426); catalogued as rs769955229, COSV50396025; called by muse, mutect2
- CYB5R4 | c.479T>C p.L160P | Missense Mutation (SNP) | VAF 32/462 reads (7%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as COSV63752476; called by muse, mutect2
- CYP4F22 | c.793C>T p.R265W | Missense Mutation (SNP) | VAF 37/746 reads (5%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.903); catalogued as rs144569785; called by muse, mutect2
- DACT3 | c.1009G>A p.A337T | Missense Mutation (SNP) | VAF 68/886 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs1230711670; called by muse, mutect2
- DCT | c.1491A>T p.R497S | Missense Mutation (SNP) | VAF 40/923 reads (4%) | SIFT deleterious (0.02); PolyPhen benign (0.323); catalogued as COSV65470280; called by muse, mutect2
- DNHD1 | c.2230G>A p.V744M | Missense Mutation (SNP) | VAF 52/762 reads (7%) | SIFT tolerated (0.14); PolyPhen benign (0.01); catalogued as rs543737354; called by muse, mutect2
- DSCAM | c.827C>T p.T276M | Missense Mutation (SNP) | VAF 51/792 reads (6%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.88); catalogued as rs752670424, COSV68022860; called by muse, mutect2
- EML1 | c.2405C>T p.T802M | Missense Mutation (SNP) | VAF 34/752 reads (5%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.605); catalogued as rs150426019; called by muse, mutect2
- F9 | c.799C>A p.H267N | Missense Mutation (SNP) | VAF 56/660 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as CD001891, CM010271; called by muse, mutect2
- FSTL5 | c.1568G>T p.R523I | Missense Mutation (SNP) | VAF 42/523 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV60210002; called by muse, mutect2
- GBA2 | c.377A>G p.Y126C | Missense Mutation (SNP) | VAF 26/534 reads (5%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.921); catalogued as COSV65239375; called by muse, mutect2
- GDF2 | c.998G>A p.R333Q | Missense Mutation (SNP) | VAF 31/934 reads (3%) | SIFT tolerated (0.33); PolyPhen benign (0.099); catalogued as rs782307807; called by muse, mutect2
- GRIN3B | c.1828C>T p.R610C | Missense Mutation (SNP) | VAF 53/834 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs145253713; called by muse, mutect2
- HDAC6 | c.3353C>T p.A1118V | Missense Mutation (SNP) | VAF 36/1025 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.374); catalogued as COSV57806423; called by muse, mutect2
- HDLBP | c.46C>T p.R16* | Nonsense Mutation (SNP) | VAF 30/580 reads (5%) | catalogued as COSV60497023; called by muse, mutect2
- KCNH5 | c.2008C>A p.L670M | Missense Mutation (SNP) | VAF 20/387 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.977); catalogued as COSV100528551; called by muse, mutect2
- KIF21B | c.2156G>A p.R719Q | Missense Mutation (SNP) | VAF 45/878 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.048); catalogued as rs1345199231, COSV59759694; called by muse, mutect2
- KRT85 | c.679G>A p.V227I | Missense Mutation (SNP) | VAF 33/618 reads (5%) | SIFT tolerated (0.06); PolyPhen benign (0.026); catalogued as rs141072357; called by muse, mutect2
- LAMP2 | c.157C>T p.R53C | Missense Mutation (SNP) | VAF 84/486 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.443); catalogued as rs752321157; ClinVar: likely benign / benign / uncertain significance; called by muse, mutect2, varscan2
- MUC5B | c.8885G>A p.R2962H | Missense Mutation (SNP) | VAF 48/910 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs752071726; called by muse, mutect2
- MYBL1 | c.1801C>T p.L601F | Missense Mutation (SNP) | VAF 18/599 reads (3%) | SIFT tolerated (0.6); PolyPhen benign (0.003); catalogued as COSV72919016; called by muse, mutect2
- MYBPC3 | c.1373G>A p.R458H | Missense Mutation (SNP) | VAF 46/726 reads (6%) | SIFT tolerated (0.16); PolyPhen benign (0.036); catalogued as rs374255707, CM043538, COSV57028188; ClinVar: uncertain significance; called by muse, mutect2
- MYMK | c.259G>A p.D87N | Missense Mutation (SNP) | VAF 40/488 reads (8%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.667); catalogued as rs750970882, COSV60601655; called by muse, mutect2
- NADK | c.191C>G p.S64C | Missense Mutation (SNP) | VAF 56/620 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs771216147; called by muse, mutect2
- NANOG | c.103T>G p.Y35D | Missense Mutation (SNP) | VAF 34/920 reads (4%) | SIFT tolerated (0.22); PolyPhen benign (0.157); catalogued as COSV57552325; called by muse, mutect2
- OR2L5 | c.530dup p.C178Lfs*2 | Frame Shift Ins (INS) | VAF 78/713 reads (11%) | catalogued as rs749963203; called by mutect2, pindel, varscan2
- OR5K2 | c.874C>G p.L292V | Missense Mutation (SNP) | VAF 10/178 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.801); catalogued as COSV71143542; called by muse, mutect2
- PCDHA13 | c.1867C>T p.R623C | Missense Mutation (SNP) | VAF 24/844 reads (3%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.226); catalogued as rs1554181269, COSV56504468; called by muse, mutect2
- PCDHA3 | c.1924G>A p.A642T | Missense Mutation (SNP) | VAF 79/522 reads (15%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.329); catalogued as COSV63540253; called by muse, mutect2, varscan2
- PCID2 | c.52G>A p.D18N | Missense Mutation (SNP) | VAF 66/479 reads (14%) | SIFT tolerated (0.89); PolyPhen benign (0); catalogued as rs766801722; called by muse, mutect2, varscan2
- PDZD2 | c.6772G>T p.V2258F | Missense Mutation (SNP) | VAF 54/944 reads (6%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as rs959182382; called by muse, mutect2
- PHF14 | c.1445C>T p.A482V | Missense Mutation (SNP) | VAF 22/514 reads (4%) | SIFT tolerated (0.2); PolyPhen benign (0.208); catalogued as rs1331801065, COSV68856093; called by muse, mutect2
- PIGQ | c.1765C>T p.R589C | Missense Mutation (SNP) | VAF 38/910 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as rs750660902, COSV99215955; called by muse, mutect2
- PIWIL1 | c.1921C>T p.R641W | Missense Mutation (SNP) | VAF 33/826 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); catalogued as rs1409689482, COSV55346048; called by muse, mutect2
- PRRX2 | c.392C>T p.A131V | Missense Mutation (SNP) | VAF 36/854 reads (4%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.996); catalogued as COSV65243393; called by muse, mutect2
- PTCHD3 | c.1009G>A p.V337M | Missense Mutation (SNP) | VAF 48/962 reads (5%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.458); catalogued as rs573539258; called by muse, mutect2
- RASGRP4 | c.1645C>T p.R549* | Nonsense Mutation (SNP) | VAF 72/752 reads (10%) | catalogued as rs1300344441; called by muse, mutect2
- RBM34 | c.514A>T p.I172F | Missense Mutation (SNP) | VAF 43/588 reads (7%) | SIFT tolerated (0.16); PolyPhen benign (0.005); catalogued as rs906098978; called by muse, mutect2
- RCE1 | c.376C>A p.L126I | Missense Mutation (SNP) | VAF 40/660 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.714); catalogued as COSV58992953, COSV58994586; called by muse, mutect2
- RTL1 | c.386C>T p.S129L | Missense Mutation (SNP) | VAF 58/1040 reads (6%) | SIFT tolerated, low confidence (0.65); PolyPhen benign (0.001); catalogued as rs745813960, COSV66017310; called by muse, mutect2
- SEMA3E | c.1940C>A p.S647* | Nonsense Mutation (SNP) | VAF 27/587 reads (5%) | catalogued as COSV57093901; called by muse, mutect2
- SERPINE3 | c.683C>T p.T228M | Missense Mutation (SNP) | VAF 66/493 reads (13%) | SIFT tolerated (0.84); PolyPhen benign (0.014); catalogued as rs370690370; called by muse, mutect2, varscan2
- SH2D3A | c.1077G>C p.L359F | Missense Mutation (SNP) | VAF 32/649 reads (5%) | SIFT deleterious (0.04); PolyPhen benign (0.437); catalogued as COSV55588589; called by muse, mutect2
- SIPA1L2 | c.3619G>A p.D1207N | Missense Mutation (SNP) | VAF 33/561 reads (6%) | SIFT tolerated (0.22); PolyPhen benign (0.001); catalogued as COSV53389170; called by muse, mutect2
- SLCO6A1 | c.133G>A p.G45R | Missense Mutation (SNP) | VAF 30/726 reads (4%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as rs1470127220, COSV65809287; called by muse, mutect2
- TAF2 | c.970A>G p.I324V | Missense Mutation (SNP) | VAF 36/446 reads (8%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.794); catalogued as rs774563468; called by muse, mutect2
- TBCK | c.451A>G p.I151V | Missense Mutation (SNP) | VAF 19/343 reads (6%) | SIFT tolerated (0.12); PolyPhen benign (0.107); catalogued as rs1374629687; called by muse, mutect2
- TENM4 | c.536C>T p.P179L | Missense Mutation (SNP) | VAF 93/819 reads (11%) | SIFT tolerated, low confidence (0.19); PolyPhen possibly damaging (0.832); catalogued as rs1330613710; called by muse, varscan2
- TP53 | c.989T>G p.L330R | Missense Mutation (SNP) | VAF 59/499 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV52677086, COSV52758102, COSV52857788, COSV53683887; called by muse, mutect2, varscan2
- TP73 | c.16G>A p.A6T | Missense Mutation (SNP) | VAF 29/628 reads (5%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as rs763021753; called by muse, mutect2
- UNC13C | c.749T>G p.L250R | Missense Mutation (SNP) | VAF 30/669 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV52852638; called by muse, mutect2
- UNC13C | c.5815C>G p.Q1939E | Missense Mutation (SNP) | VAF 11/218 reads (5%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.987); catalogued as rs1269399105; called by muse, mutect2
- WDFY2 | c.824G>C p.R275T | Missense Mutation (SNP) | VAF 30/520 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV53288183, COSV53291130; called by muse, mutect2
- ZIC4 | c.833C>G p.P278R | Missense Mutation (SNP) | VAF 55/868 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67173250; called by muse, mutect2
- ZNF354C | c.754A>C p.T252P | Missense Mutation (SNP) | VAF 43/940 reads (5%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as COSV59608122; called by muse, mutect2
- A2ML1 | c.1464C>A p.S488R | Missense Mutation (SNP) | VAF 22/496 reads (4%) | SIFT tolerated (0.52); PolyPhen benign (0.18); called by muse, mutect2
- AMOT | c.1010C>G p.P337R | Missense Mutation (SNP) | VAF 44/1253 reads (4%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.188); called by muse, mutect2
- BDNF | c.647G>A p.R216Q | Missense Mutation (SNP) | VAF 43/719 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- BPIFB3 | c.620G>A p.G207D | Missense Mutation (SNP) | VAF 22/744 reads (3%) | SIFT deleterious (0.05); PolyPhen benign (0.091); called by muse, mutect2
- BRWD3 | c.4998G>T p.K1666N | Missense Mutation (SNP) | VAF 48/942 reads (5%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.055); called by muse, mutect2
- C2CD5 | c.1357A>T p.R453W | Missense Mutation (SNP) | VAF 16/468 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); called by muse, mutect2
- CACNA2D1 | c.918C>A p.H306Q | Missense Mutation (SNP) | VAF 27/457 reads (6%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.588); called by muse, mutect2
- CASP5 | c.8-5G>C | Splice Region (SNP) | VAF 27/352 reads (8%) | called by muse, mutect2
- CFH | c.3674A>T p.Y1225F | Missense Mutation (SNP) | VAF 39/550 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- CLN6 | c.22G>T p.E8* | Nonsense Mutation (SNP) | VAF 34/431 reads (8%) | called by muse, mutect2
- CNOT6 | c.1348A>T p.S450C | Missense Mutation (SNP) | VAF 32/860 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.049); called by muse, mutect2
- COL4A4 | c.3566A>C p.K1189T | Missense Mutation (SNP) | VAF 32/636 reads (5%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.775); called by muse, mutect2
- CPVL | c.392G>A p.S131N | Missense Mutation (SNP) | VAF 30/665 reads (5%) | SIFT tolerated (0.21); PolyPhen benign (0.02); called by muse, mutect2
- CRYBG3 | c.2420C>G p.A807G | Missense Mutation (SNP) | VAF 35/453 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.209); called by muse, mutect2
- DARS2 | c.927A>C p.K309N | Missense Mutation (SNP) | VAF 40/938 reads (4%) | SIFT tolerated (0.15); PolyPhen benign (0.29); called by muse, mutect2
- DHX30 | c.2179A>C p.I727L (on ENST00000445061 / NM_138615.3; = p.I688L on NM_014966.3) | Missense Mutation (SNP) | VAF 48/786 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.866); called by muse, mutect2
- ETDA | c.54G>C p.K18N | Missense Mutation (SNP) | VAF 27/109 reads (25%) | SIFT tolerated, low confidence (0.05); PolyPhen possibly damaging (0.899); called by mutect2, varscan2
- FRMD5 | c.829C>T p.P277S | Missense Mutation (SNP) | VAF 34/619 reads (5%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); called by muse, mutect2
- GFPT2 | c.850G>C p.A284P | Missense Mutation (SNP) | VAF 34/748 reads (5%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.822); called by muse, mutect2
- GPR37 | c.611T>A p.L204Q | Missense Mutation (SNP) | VAF 54/991 reads (5%) | SIFT tolerated (0.27); PolyPhen benign (0.123); called by muse, mutect2
- HR | c.3457T>G p.C1153G | Missense Mutation (SNP) | VAF 30/690 reads (4%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.502); called by muse, mutect2
- ITGA1 | c.1697C>G p.P566R | Missense Mutation (SNP) | VAF 50/843 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.62); called by muse, mutect2
- KDM2A | c.55C>T p.R19* | Nonsense Mutation (SNP) | VAF 30/1213 reads (2%) | called by muse, mutect2
- KLHL32 | c.1376A>T p.Q459L | Missense Mutation (SNP) | VAF 30/548 reads (5%) | SIFT tolerated (0.06); PolyPhen benign (0.383); called by muse, mutect2
- LRFN2 | c.316C>A p.H106N | Missense Mutation (SNP) | VAF 60/920 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2
- LRP1B | c.7048A>C p.T2350P | Missense Mutation (SNP) | VAF 49/464 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.21); called by muse, mutect2, varscan2
- MAP7 | c.1434G>C p.E478D | Missense Mutation (SNP) | VAF 60/1016 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- MID2 | c.1350G>C p.K450N | Missense Mutation (SNP) | VAF 35/1012 reads (3%) | SIFT tolerated (0.26); PolyPhen benign (0.057); called by muse, mutect2
- MROH6 | c.359T>A p.L120Q | Missense Mutation (SNP) | VAF 59/1096 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.823); called by muse, mutect2
- MYO15A | c.1199T>G p.F400C | Missense Mutation (SNP) | VAF 66/861 reads (8%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.247); called by muse, mutect2
- NCOR1 | c.3182C>T p.T1061I | Missense Mutation (SNP) | VAF 26/465 reads (6%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.996); called by muse, mutect2
- OR6N2 | c.745C>T p.L249F | Missense Mutation (SNP) | VAF 43/690 reads (6%) | SIFT tolerated (0.06); PolyPhen benign (0.079); called by muse, mutect2
- PGAP1 | c.147+1G>A p.X49_splice | Splice Site (SNP) | VAF 18/315 reads (6%) | called by muse, mutect2
- PGBD5 | c.596C>T p.A199V (on ENST00000525115; = p.A268V on NM_001258311.2) | Missense Mutation (SNP) | VAF 32/626 reads (5%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.589); called by muse, mutect2
- PPFIA4 | c.470T>G p.L157R | Missense Mutation (SNP) | VAF 23/606 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- PPP1R9B | c.1449C>A p.Y483* | Nonsense Mutation (SNP) | VAF 38/809 reads (5%) | called by muse, mutect2
- PTGES3L-AARSD1 | c.942G>A p.V314= (on ENST00000421990 / NM_001136042.2; = p.V296= on NM_025267.3) | Splice Region (SNP) | VAF 61/479 reads (13%) | called by muse, mutect2, varscan2
- RHOXF2B | c.266T>G p.L89R | Missense Mutation (SNP) | VAF 157/666 reads (24%) | SIFT tolerated (0.69); PolyPhen benign (0.06); called by muse, mutect2, varscan2
- RNPC3 | c.731C>G p.S244* | Nonsense Mutation (SNP) | VAF 21/615 reads (3%) | called by muse, mutect2
- RP1L1 | c.6679G>A p.G2227S | Missense Mutation (SNP) | VAF 68/1118 reads (6%) | SIFT tolerated (0.18); PolyPhen benign (0); called by muse, mutect2
- RYR2 | c.4732C>A p.P1578T | Missense Mutation (SNP) | VAF 44/736 reads (6%) | SIFT tolerated (0.31); PolyPhen benign (0.067); called by muse, mutect2
- SCAP | c.431A>T p.E144V | Missense Mutation (SNP) | VAF 44/500 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.84); called by muse, mutect2
- SH2B3 | c.673C>A p.R225S | Missense Mutation (SNP) | VAF 54/968 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); called by muse, mutect2
- SLC25A43 | c.133G>A p.V45M | Missense Mutation (SNP) | VAF 58/1191 reads (5%) | SIFT tolerated (0.23); PolyPhen benign (0.01); called by muse, mutect2
- SVEP1 | c.6701G>A p.G2234D | Missense Mutation (SNP) | VAF 26/524 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- TBC1D10C | c.41A>C p.E14A | Missense Mutation (SNP) | VAF 51/1827 reads (3%) | SIFT deleterious (0.03); PolyPhen benign (0.015); called by muse, mutect2
- TLR3 | c.1630C>T p.R544W | Missense Mutation (SNP) | VAF 26/590 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.783); called by muse, mutect2
- TNRC6B | c.2843G>T p.G948V (on ENST00000454349 / NM_001162501.2; = p.G201V on NM_001024843.1) | Missense Mutation (SNP) | VAF 33/616 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- TTC1 | c.126G>T p.Q42H | Missense Mutation (SNP) | VAF 38/740 reads (5%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0); called by muse, mutect2
- U2SURP | c.2432C>G p.S811C | Missense Mutation (SNP) | VAF 18/428 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.785); called by muse, mutect2
- URB1 | c.6179G>T p.R2060M | Missense Mutation (SNP) | VAF 58/882 reads (7%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.72); called by muse, mutect2
- VWC2L | c.346T>G p.C116G | Missense Mutation (SNP) | VAF 39/488 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- ZNF713 | c.365G>A p.G122E (on ENST00000633730 / NM_001366796.2; = p.G135E on NM_182633.3) | Missense Mutation (SNP) | VAF 38/826 reads (5%) | SIFT tolerated (1); PolyPhen benign (0.01); called by muse, mutect2
- ZNF717 | c.2480C>A p.S827* | Nonsense Mutation (SNP) | VAF 35/755 reads (5%) | called by muse, mutect2
- APBA1 | c.717C>T p.D239= | Silent (SNP) | VAF 60/868 reads (7%) | catalogued as rs773533052; called by muse, mutect2
- C10orf71 | c.3645G>A p.E1215= | Silent (SNP) | VAF 94/1044 reads (9%) | called by muse, mutect2
- C11orf65 | c.783C>T p.F261= | Silent (SNP) | VAF 62/420 reads (15%) | called by muse, varscan2
- CIC | c.1866A>G p.Q622= | Silent (SNP) | VAF 46/780 reads (6%) | catalogued as rs1190034099; called by muse, mutect2
- CYP3A7 | c.714C>T p.I238= | Silent (SNP) | VAF 28/350 reads (8%) | catalogued as rs201829631; called by muse, mutect2
- DACT3 | c.651G>A p.T217= | Silent (SNP) | VAF 36/642 reads (6%) | catalogued as rs1448878180; called by muse, mutect2
- DOCK11 | c.1134C>A p.I378= | Silent (SNP) | VAF 78/558 reads (14%) | catalogued as COSV99354928; called by mutect2, varscan2
- FPR2 | c.309C>T p.I103= | Silent (SNP) | VAF 44/849 reads (5%) | catalogued as rs780942586, COSV60674534; called by muse, mutect2
- GPC4 | c.564A>G p.E188= | Silent (SNP) | VAF 38/1209 reads (3%) | called by muse, mutect2
- GPR27 | c.327C>T p.A109= | Silent (SNP) | VAF 18/466 reads (4%) | catalogued as COSV55205125; called by muse, mutect2
- GSDMB | c.585G>A p.R195= | Silent (SNP) | VAF 40/672 reads (6%) | called by muse, mutect2
- KCNJ5 | c.312C>T p.F104= | Silent (SNP) | VAF 54/937 reads (6%) | catalogued as rs201217363; ClinVar: benign; called by muse, mutect2
- KIAA0100 | c.4437C>G p.L1479= | Silent (SNP) | VAF 52/844 reads (6%) | catalogued as COSV66494394; called by muse, mutect2
- LRRC72 | c.222T>G p.L74= | Silent (SNP) | VAF 23/320 reads (7%) | called by muse, mutect2
- MMP16 | c.504A>G p.E168= | Silent (SNP) | VAF 32/839 reads (4%) | called by muse, mutect2
- NCF2 | c.675T>G p.A225= | Silent (SNP) | VAF 44/746 reads (6%) | called by muse, mutect2
- NEURL1 | c.81C>A p.L27= | Silent (SNP) | VAF 73/633 reads (12%) | called by muse, mutect2, varscan2
- NPBWR1 | c.606G>A p.A202= | Silent (SNP) | VAF 60/948 reads (6%) | catalogued as rs1463982106; called by muse, mutect2
- OLIG3 | c.579C>T p.N193= | Silent (SNP) | VAF 54/890 reads (6%) | called by muse, mutect2
- PAXIP1 | c.255T>C p.L85= | Silent (SNP) | VAF 38/724 reads (5%) | catalogued as rs778117509; called by muse, mutect2
- PCDHA10 | c.1791C>T p.D597= | Silent (SNP) | VAF 39/752 reads (5%) | catalogued as COSV56526069; called by muse, mutect2
- RASSF4 | c.490C>A p.R164= | Silent (SNP) | VAF 44/807 reads (5%) | called by muse, mutect2
- RNF25 | c.528A>G p.Q176= | Silent (SNP) | VAF 48/815 reads (6%) | called by muse, mutect2
- RTN4RL1 | c.924G>A p.A308= | Silent (SNP) | VAF 50/946 reads (5%) | catalogued as rs571649760; called by muse, mutect2
- SNX17 | c.1002G>A p.T334= | Silent (SNP) | VAF 33/597 reads (6%) | catalogued as rs758657705, COSV52008638; called by muse, mutect2
- STRC | c.5115A>C p.L1705= | Silent (SNP) | VAF 42/633 reads (7%) | called by muse, mutect2
- TMEM132D | c.1137G>A p.E379= | Silent (SNP) | VAF 40/550 reads (7%) | called by muse, mutect2
- TRIM75P | c.67C>T p.L23= | Silent (SNP) | VAF 28/573 reads (5%) | catalogued as rs372455656; called by muse, mutect2
- TRPV3 | c.1017C>T p.N339= | Silent (SNP) | VAF 46/718 reads (6%) | catalogued as rs148777786; called by muse, mutect2
- AL391832.3 | n.186C>T | RNA (SNP) | VAF 35/721 reads (5%) | catalogued as rs1485451559; called by muse, mutect2
- KCNQ1 | c.1514+8169G>T | Intron (SNP) | VAF 46/734 reads (6%) | catalogued as rs570781640; called by muse, mutect2
- KIAA2012 | c.1832-53G>A | Intron (SNP) | VAF 25/204 reads (12%) | called by muse, mutect2, varscan2
- PRICKLE4 | c.-626G>C | 5'UTR (SNP) | VAF 51/602 reads (8%) | called by muse, mutect2
- USH1C | c.1284+7585C>T | Intron (SNP) | VAF 50/656 reads (8%) | catalogued as COSV50019774; called by muse, mutect2
